Gene-level copy-number profile of tumor specimen C3L-00144-01 from CPTAC case C3L-00144, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.8 years (21,487 days).
Specimen C3L-00144-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e838b60d-1b23-4daa-b76f-1bb4d1741209.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00144-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/26b447b5-ec30-4d3c-aa50-6e3b56750858

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 531; copy number 1: 1,698; copy number 2: 33,781; copy number 3: 9,938; copy number 4: 10,306; copy number 5: 1,299; copy number 6: 642; copy number 7: 195; copy number 8: 82; copy number 9: 212; copy number 10: 216; copy number 11: 11.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–2): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,657 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:6,728,177–11,827,409, 113 genes, copy number 5 (broad region; genes not listed).
- chr2:11,836,933–11,836,986, 1 gene, copy number 5: MIR4262.
- chr2:94,867,486–95,505,059, 35 genes, copy number 5–6 (within-gene range 4–6): AC097374.1, TEKT4, MTCO1P48, MTCO3P45, RPS24P6, AC103563.3, AC103563.4, AC103563.5, AC103563.1, AC103563.6, AC103563.8, RN7SL575P, AC103563.7, MAL, AC103563.2, MRPS5, ZNF514, ZNF2, SLC2AXP1, AC092835.1, PROM2, KCNIP3, FABP7P2, FAHD2A, AC009238.3, AC009238.2, AC009238.1, UBTFL5, AC133104.2, AC133104.1, TRIM43B, AC009237.11, AC009237.1, AC009237.10, AC009237.2.
- chr4:49,096–88,208, 2 genes, copy number 6: BNIP3P41, ZNF595.
- chr5:58,198–45,895,970, 679 genes, copy number 7–11 (broad region; genes not listed).
- chr5:163,460,203–165,171,643, 14 genes, copy number 5: HMMR, HMMR-AS1, MAT2B, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1.
- chr6:29,555,629–29,831,125, 28 genes, copy number 5 (within-gene range 4–5): GABBR1, OR2H5P, TMEM183AP1, SNORD32B, RPL13AP, OR2H2, SUMO2P1, MOG, ZFP57, ZDHHC20P1, HLA-F, AL645939.1, HLA-F-AS1, RPL23AP1, MICE, AL645939.2, Y_RNA, IFITM4P, AL645939.4, AL645939.5, AL645939.3, HLA-V, HCG4, HLA-P, RPL7AP7, MICG, HLA-G, HCG4P8.
- chr6:46,492,052–58,438,364, 181 genes, copy number 6–10 (broad region; genes not listed).
- chr6:61,679,961–65,707,226, 29 genes, copy number 6 (within-gene range 2–6): KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr7:37,032–47,582,558, 827 genes, copy number 5–6 (broad region; genes not listed).
- chr9:12,134–73,865, 5 genes, copy number 6 (within-gene range 2–6): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr11:135,061,781–135,075,908, 1 gene, copy number 6: LINC02684.
- chr16:90,173,217–90,222,851, 2 genes, copy number 5: LINC02193, CICP25.
- chr17:54,968,727–55,327,791, 4 genes, copy number 7 (within-gene range 4–7): STXBP4, HLF, AC007638.2, AC007638.1.
- chr17:59,893,046–82,490,537, 732 genes, copy number 5–7 (broad region; genes not listed).
- chr19:58,573,503–58,605,223, 4 genes, copy number 6 (within-gene range 3–6): CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.

Autosomal genes at a single copy (total copy number 1): 161. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
